Somatic mutation profile of tumor specimen TCGA-LT-A8JT-01A (aliquot TCGA-LT-A8JT-01A-11D-A364-08) from TCGA case TCGA-LT-A8JT, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 69.8 years (25,498 days).
Specimen TCGA-LT-A8JT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 266703cd-e899-4b9e-9ed4-4c049c3081a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LT-A8JT-10A (Blood Derived Normal), aliquot TCGA-LT-A8JT-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72efbbcd-9a15-4ef7-9d68-5fedf52a9337

The open-access MAF lists 89 somatic variants for this specimen: 68 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 55, Silent 21, Nonsense Mutation 7, In Frame Del 2, Splice Site 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 19/19 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.296T>C p.M99T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101557853; called by muse, mutect2, varscan2
- ANKRD17 | c.2978C>A p.A993E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.979); catalogued as COSV58218109; called by muse, mutect2, varscan2
- BOD1L1 | c.4000G>A p.E1334K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1188486659, COSV50008836; called by muse, mutect2, varscan2
- BOLL | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV56573777; called by muse, mutect2, varscan2
- BRCA1 | c.2738A>G p.N913S | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs199954851, COSV58787181; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C3orf14 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV51706534; called by muse, mutect2, varscan2
- CCT2 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54739157, COSV54739675; called by muse, mutect2, varscan2
- CDYL | c.748G>A p.E250K (on ENST00000328908 / NM_001368125.1; = p.E196K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs372980060, COSV59360015; called by muse, mutect2, varscan2
- CHEK1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV54022744; called by muse, mutect2, varscan2
- CKMT2 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54172614; called by mutect2, varscan2
- COL20A1 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs751167506, COSV58914495; called by muse, mutect2, varscan2
- CREBBP | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 30/104 reads (29%) | catalogued as COSV99270598; called by muse, mutect2, varscan2
- CRIM1 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs773874517, COSV54861728; called by muse, mutect2, varscan2
- CROT | c.1208C>G p.S403C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV58973474, COSV58975419; called by muse, mutect2, varscan2
- CSF1 | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.433); catalogued as COSV60032530; called by muse, mutect2, varscan2
- DACT1 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs747368131; called by muse, mutect2, varscan2
- DDB1 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57101932; called by muse, mutect2, varscan2
- DHRS7B | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 27/50 reads (54%) | catalogued as COSV100683993, COSV60887907; called by muse, mutect2, varscan2
- DMRTB1 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV65112874; called by muse, mutect2, varscan2
- EEF1A1 | c.499T>G p.Y167D | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as COSV58550170; called by muse, mutect2, varscan2
- EXOC5 | c.1700A>G p.N567S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs1432639004, COSV61770478; called by muse, mutect2, varscan2
- F8 | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64271458; called by muse, mutect2, varscan2
- FAM135B | c.1271G>A p.S424N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52715751; called by muse, mutect2, varscan2
- FBN1 | c.8521G>C p.E2841Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as CM118006, COSV57310584, COSV57313168; called by muse, mutect2, varscan2
- GUCY2C | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474482729, COSV53788069; called by muse, mutect2, varscan2
- HEXB | c.1421C>T p.T474I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV54667305; called by muse, mutect2, varscan2
- KDM4D | c.1325_1327del p.Q442_I443delinsL | In Frame Del (DEL) | VAF 27/83 reads (33%) | catalogued as COSV58634151; called by mutect2, pindel, varscan2
- KIAA1109 | c.14524G>T p.E4842* | Nonsense Mutation (SNP) | VAF 36/73 reads (49%) | catalogued as COSV99166045; called by muse, mutect2, varscan2
- KIF26B | c.5351C>T p.T1784M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as rs765451111, COSV100832723; called by muse, mutect2, varscan2
- NCOA1 | c.3703G>A p.A1235T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99946397; called by muse, mutect2
- NEO1 | c.3104G>A p.R1035Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs759379757, COSV56069460; called by muse, mutect2, varscan2
- OR4S2 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 82/208 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56746387; called by muse, mutect2
- OR4S2 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV56746397; called by muse, mutect2, varscan2
- OR56B1 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV57722688; called by muse, mutect2, varscan2
- OVCH1 | c.2579C>T p.T860I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs1423291181, COSV58961339; called by muse, mutect2, varscan2
- PCDHA3 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1305664229, COSV63540217; called by muse, mutect2, varscan2
- PCDHB10 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53377223; called by muse, mutect2, varscan2
- PKD1 | c.9659C>T p.S3220L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144246138; called by muse, varscan2
- POGZ | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55034049; called by muse, mutect2, varscan2
- POLE | c.4124C>T p.A1375V | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs766168647, COSV57677415; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RARG | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58432377; called by muse, mutect2, varscan2
- RNF25 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.32); catalogued as rs772481330, COSV55306635; called by muse, varscan2
- RPRD1B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV65032536; called by muse, mutect2, varscan2
- SCN5A | c.4057G>A p.V1353M (on ENST00000333535 / NM_198056.3; = p.V1352M on NM_000335.5) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs199473233, CM100708, COSV61114948; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- SCP2 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV65260845; called by muse, mutect2, varscan2
- SEZ6 | c.2446C>T p.R816C | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757335969, COSV57978661; called by muse, mutect2
- SLC25A2 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53403437; called by muse, mutect2, varscan2
- SLC26A3 | c.1483C>G p.Q495E | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100385142, COSV60642687; called by muse, mutect2, varscan2
- SLCO2B1 | c.1548C>A p.C516* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as rs1331031853, COSV99214752; called by muse, mutect2, varscan2
- SP8 | c.575C>T p.S192L (on ENST00000361443 / NM_198956.4; = p.S210L on NM_182700.6) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.216); catalogued as rs1391027524, COSV100815376; called by muse, mutect2, varscan2
- SPANXN2 | c.79-1G>A p.X27_splice | Splice Site (SNP) | VAF 5/98 reads (5%) | catalogued as COSV65128115; called by muse, mutect2
- TAS2R1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs145804099, COSV101225699; called by muse, mutect2, varscan2
- TEK | c.2231G>A p.G744E | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs923057858, COSV66228434; called by muse, mutect2, varscan2
- THOC5 | c.1147A>G p.M383V | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs755649674, COSV63798201; called by muse, mutect2, varscan2
- TKFC | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV67523436; called by muse, mutect2, varscan2
- USP48 | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 36/98 reads (37%) | catalogued as COSV57613298; called by muse, mutect2, varscan2
- ZNF205 | c.1553A>T p.N518I | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54620464; called by muse, mutect2, varscan2
- ZNF208 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as rs371199411, COSV101237067; called by muse, mutect2, varscan2
- ZNF300 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as COSV99199903; called by muse, mutect2, varscan2
- ZNF512B | c.2166C>T p.L722= | Splice Region (SNP) | VAF 17/48 reads (35%) | catalogued as rs1453229099, COSV53868285; called by muse, mutect2, varscan2
- ZNF516 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV71586864; called by muse, mutect2, varscan2
- ZNF587 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100299556; called by muse, mutect2, varscan2
- ZNF804A | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV56442450; called by muse, mutect2, varscan2
- ZNRF3 | c.744G>A p.Q248= (on ENST00000544604 / NM_001206998.2; = p.Q148= on NM_032173.3) | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as COSV60432577; called by muse, mutect2, varscan2
- ENOX1 | c.1555-9_1555-2del p.X519_splice | Splice Site (DEL) | VAF 34/89 reads (38%) | called by mutect2, pindel, varscan2
- POLR2A | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTAN1 | c.5501_5503del p.N1834del | In Frame Del (DEL) | VAF 14/24 reads (58%) | called by pindel, varscan2
- ANKFN1 | c.282C>T p.N94= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs201436645, COSV59441624; called by muse, mutect2, varscan2
- CLPTM1 | c.1584C>T p.F528= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV61611553; called by muse, mutect2, varscan2
- FOXP4 | c.252G>T p.L84= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV57219107, COSV57224540; called by muse, mutect2, varscan2
- KCNF1 | c.63C>T p.D21= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs949096262, COSV54462817; called by muse, mutect2, varscan2
- LHX2 | c.813G>T p.T271= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as COSV65318040; called by muse, mutect2
- MSH6 | c.2358T>C p.Y786= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as rs923165627, COSV52276749; called by muse, mutect2, varscan2
- PAPPA | c.4863C>T p.L1621= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as rs145760251, COSV60277957; called by muse, mutect2, varscan2
- PCDHGA9 | c.1395C>T p.N465= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1451476815, COSV53922955; called by muse, mutect2, varscan2
- PCDHGB5 | c.1728C>T p.R576= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV99534590; called by muse, mutect2, varscan2
- PDXK | c.909A>G p.P303= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs780098982, COSV99376471; called by muse, varscan2
- PLIN4 | c.4005G>A p.E1335= (on ENST00000301286; = p.E1350= on NM_001367868.2) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1359072098, COSV100012310, COSV100012317; called by muse, mutect2, varscan2
- PTCHD1 | c.546C>T p.D182= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as rs758901997, COSV65059605; called by muse, mutect2, varscan2
- PTK2 | c.2760G>A p.S920= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs370475701; called by muse, mutect2, varscan2
- RASGRP4 | c.1561C>T p.L521= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1420168515, COSV99385033; called by muse, mutect2, varscan2
- SATB2 | c.1881G>A p.G627= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs1327885665, COSV53481268; called by muse, mutect2, varscan2
- SLC17A7 | c.1449C>T p.V483= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV55547139; called by muse, mutect2, varscan2
- SLITRK2 | c.2526C>T p.I842= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs1569507254, COSV59424247; called by muse, mutect2, varscan2
- STAB1 | c.1881G>C p.V627= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV58734139; called by muse, mutect2, varscan2
- TRAPPC9 | c.2907G>A p.E969= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV66896436; called by muse, mutect2, varscan2
- UTRN | c.6264G>A p.K2088= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs753584528, COSV62331778; called by muse, varscan2
- ZNF277 | c.1092G>A p.V364= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV62463768; called by muse, mutect2, varscan2
